Somatic mutation profile of tumor specimen TCGA-MH-A561-01A (aliquot TCGA-MH-A561-01A-11D-A26P-10) from TCGA case TCGA-MH-A561, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Age at diagnosis: 66.5 years (24,271 days).
Specimen TCGA-MH-A561-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 289b2f9b-f14b-4b3e-b766-0e8e85e9d8d7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-MH-A561-10A (Blood Derived Normal), aliquot TCGA-MH-A561-10A-01D-A26P-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7dd78560-3fa4-443a-826e-c2aefc8c4173

The open-access MAF lists 110 somatic variants for this specimen: 87 protein-altering or splice-affecting, 14 silent, 9 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 63, Silent 14, Frame Shift Del 12, 3'UTR 6, Nonsense Mutation 3, Frame Shift Ins 3, Nonstop Mutation 2, In Frame Del 2, Splice Site 2, Intron 2, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- MET | c.3749T>C p.M1250T | Missense Mutation (SNP) | VAF 24/74 reads (32%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121913245, CM992181, COSV59255872; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- AATK | c.2422C>A p.P808T (on ENST00000326724 / NM_001080395.3; = p.P705T on NM_004920.2) | Missense Mutation (SNP) | VAF 14/55 reads (25%) | SIFT tolerated (0.29); PolyPhen benign (0.003); catalogued as COSV58366504; called by muse, mutect2, varscan2
- ADAMTSL3 | c.2069G>A p.R690H | Missense Mutation (SNP) | VAF 66/207 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as rs148020587, COSV54447515; called by muse, mutect2, varscan2
- ADORA2A | c.340G>T p.G114C | Missense Mutation (SNP) | VAF 46/119 reads (39%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.932); catalogued as COSV58378924; called by muse, mutect2, varscan2
- AGBL4 | c.1510T>C p.*504Qext*27 | Nonstop Mutation (SNP) | VAF 18/139 reads (13%) | catalogued as COSV61892713; called by muse, mutect2, varscan2
- AQP10 | c.751G>T p.V251L | Missense Mutation (SNP) | VAF 16/33 reads (48%) | SIFT tolerated (0.58); PolyPhen benign (0.188); catalogued as COSV59246049; called by muse, mutect2, varscan2
- ATP11A | c.3053T>C p.L1018P | Missense Mutation (SNP) | VAF 29/68 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.841); catalogued as COSV52111373; called by muse, mutect2, varscan2
- AUP1 | c.645C>A p.F215L | Missense Mutation (SNP) | VAF 21/55 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV51207487; called by muse, mutect2, varscan2
- BOD1L1 | c.6779C>T p.S2260L | Missense Mutation (SNP) | VAF 16/141 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.657); catalogued as COSV50012659; called by muse, mutect2, varscan2
- C2orf69 | c.403G>T p.A135S | Missense Mutation (SNP) | VAF 30/85 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as COSV60666484; called by muse, mutect2, varscan2
- CACNA1S | c.1953C>G p.I651M | Missense Mutation (SNP) | VAF 45/135 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV62939355; called by muse, mutect2, varscan2
- CBX6 | c.1123A>C p.S375R | Missense Mutation (SNP) | VAF 30/96 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.724); catalogued as COSV53320813; called by muse, mutect2, varscan2
- CDC20 | c.1101G>C p.Q367H | Missense Mutation (SNP) | VAF 30/77 reads (39%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.469); catalogued as COSV60522117; called by muse, mutect2, varscan2
- CENPF | c.7783A>T p.N2595Y | Missense Mutation (SNP) | VAF 21/50 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.601); catalogued as COSV65274906; called by muse, mutect2, varscan2
- CHRM1 | c.1366C>T p.P456S | Missense Mutation (SNP) | VAF 13/60 reads (22%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.011); catalogued as COSV61006662; called by muse, mutect2, varscan2
- CHRM1 | c.1063T>A p.F355I | Missense Mutation (SNP) | VAF 24/57 reads (42%) | SIFT tolerated (0.53); PolyPhen benign (0.017); catalogued as COSV61006673; called by muse, mutect2, varscan2
- CSMD3 | c.8222C>T p.P2741L | Missense Mutation (SNP) | VAF 49/127 reads (39%) | SIFT deleterious (0.02); PolyPhen benign (0.111); catalogued as COSV52159975; called by muse, mutect2, varscan2
- DGKD | c.2916G>T p.M972I (on ENST00000264057 / NM_152879.3; = p.M928I on NM_003648.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 132/347 reads (38%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as COSV51046687, COSV51049750; called by muse, mutect2, varscan2
- DNAH1 | c.7889T>C p.L2630P | Missense Mutation (SNP) | VAF 52/131 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.596); catalogued as COSV70228961; called by muse, mutect2, varscan2
- E2F2 | c.570C>G p.I190M | Missense Mutation (SNP) | VAF 42/110 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as COSV100674860, COSV62276429; called by muse, mutect2, varscan2
- EDC4 | c.434T>G p.L145W | Missense Mutation (SNP) | VAF 48/113 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.903); catalogued as COSV54646031; called by muse, mutect2, varscan2
- ELMO1 | c.1304G>A p.S435N | Missense Mutation (SNP) | VAF 27/79 reads (34%) | SIFT tolerated (0.19); PolyPhen benign (0.007); catalogued as COSV60304278; called by muse, mutect2, varscan2
- EPM2AIP1 | c.1086G>T p.L362F | Missense Mutation (SNP) | VAF 9/58 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as COSV51617835; called by muse, mutect2, varscan2
- FAM186A | c.5483C>A p.S1828Y | Missense Mutation (SNP) | VAF 31/66 reads (47%) | SIFT tolerated (0.27); PolyPhen benign (0.168); catalogued as COSV59248113; called by muse, mutect2, varscan2
- FAM72C | c.293_295del p.N98del | In Frame Del (DEL) | VAF 159/720 reads (22%) | catalogued as rs1553518137; called by pindel, varscan2
- FBXO11 | c.2063G>A p.G688E (on ENST00000403359 / NM_001190274.2; = p.G604E on NM_025133.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 5/44 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52279190; called by muse, mutect2
- FBXW7 | c.1177del p.R393Efs*2 (on ENST00000281708 / NM_001349798.2; = p.R313Efs*2 on NM_018315.5) | Frame Shift Del (DEL) | VAF 31/98 reads (32%) | catalogued as COSV55892695; called by mutect2, pindel, varscan2
- FNBP1L | c.136T>A p.L46M | Missense Mutation (SNP) | VAF 42/91 reads (46%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as COSV53093307; called by muse, mutect2, varscan2
- GAD1 | c.675G>T p.M225I | Missense Mutation (SNP) | VAF 36/108 reads (33%) | SIFT deleterious (0.04); PolyPhen benign (0.162); catalogued as COSV60152329; called by muse, mutect2, varscan2
- GCN1 | c.7343G>A p.G2448E | Missense Mutation (SNP) | VAF 24/158 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV56107635; called by muse, mutect2, varscan2
- GID8 | c.421A>G p.T141A | Missense Mutation (SNP) | VAF 14/216 reads (6%) | SIFT tolerated (0.58); PolyPhen benign (0.015); catalogued as rs1482774457, COSV56611468; called by muse, mutect2
- GPHN | c.228A>C p.E76D | Missense Mutation (SNP) | VAF 19/69 reads (28%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as COSV59480163; called by muse, mutect2
- GRID2 | c.932A>G p.D311G | Missense Mutation (SNP) | VAF 23/78 reads (29%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.989); catalogued as COSV56204429; called by muse, mutect2, varscan2
- IGSF10 | c.973G>A p.G325R | Missense Mutation (SNP) | VAF 44/110 reads (40%) | SIFT deleterious (0.03); PolyPhen benign (0.066); catalogued as rs747336028, COSV56785067, COSV56790716; called by muse, mutect2, varscan2
- INS | c.280C>A p.Q94K | Missense Mutation (SNP) | VAF 17/47 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.511); catalogued as COSV51747101; called by muse, mutect2, varscan2
- ITGA2B | c.3061-1G>A p.X1021_splice | Splice Site (SNP) | VAF 20/88 reads (23%) | catalogued as CS153680, COSV99288726; called by muse, mutect2, varscan2
- KIF13A | c.1804G>A p.V602I | Missense Mutation (SNP) | VAF 37/119 reads (31%) | SIFT tolerated (0.75); PolyPhen benign (0.034); catalogued as rs1210948997, COSV52450840; called by muse, mutect2, varscan2
- KIN | c.280G>C p.V94L | Missense Mutation (SNP) | VAF 54/142 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as COSV65430570; called by muse, mutect2, varscan2
- KMT2E | c.897G>C p.E299D | Missense Mutation (SNP) | VAF 17/154 reads (11%) | SIFT tolerated, low confidence (0.07); PolyPhen possibly damaging (0.754); catalogued as COSV57573187; called by muse, mutect2, varscan2
- LIMD1 | c.1041T>G p.S347R | Missense Mutation (SNP) | VAF 76/225 reads (34%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as COSV56267271; called by muse, mutect2
- LRP2 | c.1438A>T p.K480* | Nonsense Mutation (SNP) | VAF 23/75 reads (31%) | catalogued as COSV55552732; called by muse, mutect2, varscan2
- MEIOC | c.917A>T p.Q306L | Missense Mutation (SNP) | VAF 14/39 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.202); catalogued as COSV63440111; called by muse, mutect2, varscan2
- METAP1D | c.469A>G p.N157D | Missense Mutation (SNP) | VAF 50/152 reads (33%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.631); catalogued as COSV59930158; called by muse, varscan2
- MR1 | c.5G>T p.G2V | Missense Mutation (SNP) | VAF 44/143 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as COSV51580781, COSV51582400; called by muse, mutect2, varscan2
- MSTN | c.142A>G p.T48A | Missense Mutation (SNP) | VAF 20/45 reads (44%) | SIFT tolerated (0.59); PolyPhen benign (0.014); catalogued as COSV53620974; called by muse, mutect2, varscan2
- MYLK3 | c.351G>T p.M117I | Missense Mutation (SNP) | VAF 44/87 reads (51%) | SIFT tolerated (0.15); PolyPhen benign (0.165); catalogued as COSV67364218; called by muse, mutect2, varscan2
- MYO15A | c.8060C>G p.A2687G | Missense Mutation (SNP) | VAF 70/290 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.167); catalogued as rs747345225, COSV52756540; called by muse, mutect2
- NCAPD3 | c.1787G>A p.R596Q | Missense Mutation (SNP) | VAF 13/89 reads (15%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.982); catalogued as rs1363708099, COSV73258381; called by muse, mutect2, varscan2
- NCOA2 | c.2867C>T p.P956L | Missense Mutation (SNP) | VAF 26/142 reads (18%) | SIFT tolerated (0.46); PolyPhen benign (0.01); catalogued as rs767352400, COSV51219332; called by muse, mutect2, varscan2
- NFIA | c.902C>A p.P301Q | Missense Mutation (SNP) | VAF 78/244 reads (32%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.999); catalogued as COSV64537425; called by muse, mutect2, varscan2
- NOL9 | c.478C>T p.Q160* | Nonsense Mutation (SNP) | VAF 4/65 reads (6%) | catalogued as COSV60228047; called by muse, mutect2
- NRG1 | c.980A>T p.E327V (on ENST00000405005 / NM_013964.5; = p.E332V on NM_013956.5) | Missense Mutation (SNP) | VAF 36/131 reads (27%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.985); catalogued as COSV55159010; called by muse, mutect2, varscan2
- OVOL1 | c.804A>T p.*268Cext*59 | Nonstop Mutation (SNP) | VAF 4/42 reads (10%) | catalogued as COSV60119841; called by muse, mutect2
- PALM2AKAP2 | c.1039A>G p.T347A (on ENST00000374531 / NM_001037293.2; = p.T379A on NM_053016.6) | Missense Mutation (SNP) | VAF 18/121 reads (15%) | SIFT tolerated (0.4); PolyPhen possibly damaging (0.548); catalogued as COSV57120559; called by muse, mutect2, varscan2
- PDCD5 | c.294del p.V99* | Frame Shift Del (DEL) | VAF 39/124 reads (31%) | catalogued as rs1373819281; called by mutect2, pindel, varscan2
- PDE3B | c.1236A>T p.E412D | Missense Mutation (SNP) | VAF 54/138 reads (39%) | SIFT tolerated (0.93); PolyPhen probably damaging (0.978); catalogued as COSV56383569; called by muse, mutect2, varscan2
- PHF20L1 | c.167A>G p.E56G | Missense Mutation (SNP) | VAF 45/128 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.734); catalogued as COSV55192418; called by muse, mutect2, varscan2
- PLEKHM2 | c.1702T>G p.S568A | Missense Mutation (SNP) | VAF 50/172 reads (29%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.354); catalogued as COSV65396103; called by muse, varscan2
- PTPN3 | c.276del p.K93Sfs*3 | Frame Shift Del (DEL) | VAF 27/111 reads (24%) | catalogued as COSV99356004; called by mutect2, pindel, varscan2
- RBBP6 | c.3482A>T p.E1161V | Missense Mutation (SNP) | VAF 36/101 reads (36%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.146); catalogued as COSV60505072; called by muse, mutect2, varscan2
- RBP7 | c.264C>G p.I88M | Missense Mutation (SNP) | VAF 14/136 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.207); catalogued as COSV53812993; called by muse, mutect2, varscan2
- RPL3L | c.1159G>T p.A387S | Missense Mutation (SNP) | VAF 25/61 reads (41%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.757); catalogued as COSV51906581; called by muse, mutect2, varscan2
- RUFY3 | c.116G>T p.W39L | Missense Mutation (SNP) | VAF 86/226 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.901); catalogued as COSV56913549; called by muse, mutect2, varscan2
- SATB1 | c.2018A>G p.E673G | Missense Mutation (SNP) | VAF 66/161 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58669405; called by muse, mutect2, varscan2
- SLC28A3 | c.1469T>A p.F490Y | Missense Mutation (SNP) | VAF 57/160 reads (36%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.998); catalogued as COSV66153058; called by muse, mutect2, varscan2
- SYDE1 | c.223A>T p.S75C | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV61442106; called by muse, mutect2, varscan2
- SYTL2 | c.2430T>G p.S810R (on ENST00000528231 / NM_001162951.2; = p.S786R on NM_032943.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.148); catalogued as COSV60358988; called by mutect2, varscan2
- TAF7 | c.238A>G p.I80V | Missense Mutation (SNP) | VAF 29/85 reads (34%) | SIFT tolerated (0.58); PolyPhen benign (0.007); catalogued as COSV57665229; called by muse, mutect2, varscan2
- TFAP2A | c.1281C>G p.N427K (on ENST00000482890; = p.N419K on NM_001032280.3) | Missense Mutation (SNP) | VAF 42/136 reads (31%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as COSV60233218, COSV60233307; called by muse, varscan2
- UPF3B | c.361G>C p.D121H | Missense Mutation (SNP) | VAF 112/148 reads (76%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52230009; called by muse, mutect2, varscan2
- UTP25 | c.421G>T p.E141* | Nonsense Mutation (SNP) | VAF 16/48 reads (33%) | catalogued as COSV101530948, COSV72227417; called by muse, mutect2, varscan2
- VPS13C | c.7492A>G p.T2498A (on ENST00000644861 / NM_020821.3; = p.T2455A on NM_017684.5) | Missense Mutation (SNP) | VAF 40/97 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.114); catalogued as rs771888051, COSV51177554; called by muse, mutect2, varscan2
- WDR87 | c.982C>A p.Q328K | Missense Mutation (SNP) | VAF 26/275 reads (9%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.945); catalogued as COSV58198634; called by muse, mutect2
- BACH1 | c.527_533del p.N176Mfs*35 | Frame Shift Del (DEL) | VAF 6/48 reads (13%) | called by mutect2, pindel
- C22orf31 | c.442dup p.S148Kfs*14 | Frame Shift Ins (INS) | VAF 4/20 reads (20%) | called by mutect2, pindel
- CDH24 | c.2020del p.E674Rfs*167 | Frame Shift Del (DEL) | VAF 6/22 reads (27%) | called by mutect2, pindel, varscan2
- CENPL | c.764delinsAA p.A255Efs*27 | Frame Shift Ins (INS) | VAF 17/86 reads (20%) | called by pindel, varscan2*
- CEP350 | c.125_126del p.R42Tfs*3 | Frame Shift Del (DEL) | VAF 12/62 reads (19%) | called by pindel, varscan2
- LAMB4 | c.1652_1663del p.Y551_A555delinsS | In Frame Del (DEL) | VAF 35/125 reads (28%) | called by mutect2, pindel, varscan2
- MAP3K7 | c.1641-1_1642delinsA p.X547_splice (on ENST00000369329 / NM_145331.3; = p.X520_splice on NM_003188.4) | Splice Site (DEL) | VAF 17/62 reads (27%) | called by pindel, varscan2*
- MTG1 | c.261_262insCG p.A88Rfs*14 | Frame Shift Ins (INS) | VAF 37/101 reads (37%) | called by mutect2, pindel, varscan2
- SCN10A | c.4688_4695delinsACAC p.L1563Hfs*23 | Frame Shift Del (DEL) | VAF 24/114 reads (21%) | called by pindel, varscan2*
- VPS51 | c.920del p.G307Efs*116 | Frame Shift Del (DEL) | VAF 6/18 reads (33%) | called by mutect2, pindel, varscan2
- YARS2 | c.355del p.L119Wfs*28 | Frame Shift Del (DEL) | VAF 12/46 reads (26%) | called by mutect2, pindel
- ZNF256 | c.1611del p.H537Qfs*83 | Frame Shift Del (DEL) | VAF 27/95 reads (28%) | called by mutect2, pindel, varscan2
- ZNF792 | c.548del p.N183Tfs*16 | Frame Shift Del (DEL) | VAF 89/278 reads (32%) | called by mutect2, pindel, varscan2
- ZNF831 | c.3986del p.K1329Sfs*13 | Frame Shift Del (DEL) | VAF 36/105 reads (34%) | called by mutect2, pindel, varscan2
- AAK1 | c.822C>T p.F274= | Silent (SNP) | VAF 39/112 reads (35%) | catalogued as COSV68643736; called by muse, mutect2, varscan2
- COL12A1 | c.3801A>G p.A1267= | Silent (SNP) | VAF 67/180 reads (37%) | catalogued as rs770806561, COSV59395831; called by muse, mutect2, varscan2
- COL8A2 | c.1176T>C p.I392= | Silent (SNP) | VAF 29/96 reads (30%) | catalogued as COSV57441729; called by muse, mutect2, varscan2
- FAM102A | c.999C>T p.I333= (on ENST00000373095 / NM_001035254.3; = p.I191= on NM_203305.2) | Silent (SNP) | VAF 19/35 reads (54%) | catalogued as rs753057132, COSV55947595; called by muse, mutect2, varscan2
- GALNT6 | c.933C>G p.P311= | Silent (SNP) | VAF 89/247 reads (36%) | catalogued as COSV62542202, COSV62542435; called by muse, mutect2, varscan2
- GPBP1L1 | c.12T>C p.H4= | Silent (SNP) | VAF 11/79 reads (14%) | catalogued as COSV51969299; called by muse, mutect2, varscan2
- HDAC2 | c.1248T>G p.A416= | Silent (SNP) | VAF 9/16 reads (56%) | catalogued as COSV64038144; called by muse, mutect2, varscan2
- LCT | c.4945A>C p.R1649= | Silent (SNP) | VAF 11/70 reads (16%) | catalogued as COSV51549103; called by muse, mutect2, varscan2
- METTL23 | c.123C>A p.A41= | Silent (SNP) | VAF 14/76 reads (18%) | catalogued as COSV57972311; called by muse, mutect2, varscan2
- PLTP | c.105G>A p.K35= | Silent (SNP) | VAF 30/85 reads (35%) | catalogued as COSV62464728; called by muse, mutect2, varscan2
- SCNN1B | c.219C>G p.T73= | Silent (SNP) | VAF 94/208 reads (45%) | catalogued as COSV56304230; called by muse, mutect2, varscan2
- SMC1A | c.495G>C p.A165= | Silent (SNP) | VAF 37/47 reads (79%) | catalogued as COSV59129092, COSV59129191; called by muse, mutect2, varscan2
- SPAG9 | c.2739C>A p.V913= (on ENST00000262013 / NM_001130528.3; = p.V899= on NM_003971.6) | Silent (SNP) | VAF 50/237 reads (21%) | catalogued as COSV56235355; called by muse, mutect2, varscan2
- TRPM2 | c.2664C>T p.I888= | Silent (SNP) | VAF 9/17 reads (53%) | catalogued as rs1385978075, COSV55969550; called by muse, mutect2, varscan2
- AC244258.1 | n.537G>T | RNA (SNP) | VAF 9/97 reads (9%) | called by muse, mutect2, varscan2
- CLCN1 | c.774+209_774+210del | Intron (DEL) | VAF 82/256 reads (32%) | called by mutect2, varscan2
- F8A1 | c.*376C>A | 3'UTR (SNP) | VAF 75/346 reads (22%) | called by muse, mutect2, varscan2
- FLRT2 | c.*560A>T | 3'UTR (SNP) | VAF 6/44 reads (14%) | catalogued as COSV100420223; called by muse, mutect2, varscan2
- GRIK2 | c.2563-2450del | Intron (DEL) | VAF 30/82 reads (37%) | called by mutect2, pindel, varscan2
- PCDHB7 | c.*1109T>A | 3'UTR (SNP) | VAF 9/33 reads (27%) | catalogued as COSV99176679; called by muse, mutect2, varscan2
- PSMB11 | c.*250C>A | 3'UTR (SNP) | VAF 53/140 reads (38%) | catalogued as COSV99943698; called by muse, mutect2, varscan2
- SOX12 | c.*1787T>A | 3'UTR (SNP) | VAF 36/58 reads (62%) | catalogued as COSV100705234; called by muse, mutect2, varscan2
- TRMT9B | c.*5321T>G | 3'UTR (SNP) | VAF 26/75 reads (35%) | catalogued as COSV101501543; called by muse, mutect2
